Somatic mutation profile of tumor specimen 0DR20K from CCDI case PBCFJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (410 days).
Specimen 0DR20K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dd8c1e5-a76d-4506-9296-3456c278b6f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88cac3a1-338a-42ff-a7d9-5c3268294865

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PNPLA6 | c.1880C>T p.A627V (on ENST00000414982 / NM_001166111.2; = p.A579V on NM_006702.5) | Missense Mutation (SNP) | VAF 61/527 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs568356836, COSV55377586; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HJV | c.1151C>T p.A384V (on ENST00000336751 / NM_213653.4; = p.A271V on NM_145277.5) | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
